Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3ZT, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3ZT-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Report

DOB:

Physician:

Collected:

Accession:

Received:

Case type: Surgical Case

DIAGNOSIS

- (A) LEFT THYROID LOBE AND ISTHMUS:
PAPILLARY THYROID CARCINOMA, CONVENTIONAL TYPE

Location: Left lobe

Multi-focal: No

Size = 2.5 cm

Extrathyroidal extension: Present, extending into fibroadipose tissue

Lymphovascular invasion: Present

Resection Margins: Negative

Background Thyroid: Multinodular adenomatous goiter

Lymph nodes:

No lymph nodes present

- (B) COMPLETION, RIGHT THYROID LOBE:

Multinodular adenomatous goiter, no tumor present.

ICD-0-3

carcinoma, papillary, thyroid

8260/3

Site: thyroid, NOS C73.9

fw
6/17/12

GROSS DESCRIPTION

(A) LEFT THYROID LOBE AND ISTHMUS – A thyroid lobectomy of left lobe (3.5 x 2.0 x 2.0 cm) is nearly entirely replaced by a soft pink papillary tumor with hyalinized fibrosis surrounding the nodule (2.5 x 1.5 x 0.9 cm) shows an irregular border outside of the area of fibrosis, but is confined to the thyroid. A portion of skeletal muscle is also present with the specimen.

SECTION CODE: A1, representative section for frozen assessment with touch prep; A2-A8, serial sections of the left lobe and full examination of the interface of nodule with surrounding soft tissue.

*FS/DX: PAPILLARY THYROID CARCINOMA.

(B) COMPLETION, RIGHT THYROID LOBE - A right thyroid lobe measuring 4.4 x 3.0 x 1.0 cm. Serial sectioning revealed beefy red spongy parenchyma with no grossly identifiable lesion. Representative sections from superior to inferior submitted in B1-B4.

CLINICAL HISTORY

Nodule, left thyroid.

SNOMED CODES

T-B6000, M-Y3420, T-B6000, M-80503, M-Y3420,

"Some tests reported here may have been developed and performance characteristics determined by
These tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."

[page 2 of 2]
Surgical Pathology Report

DOB
Physician:

Accession.

Collected:
Received:

Pathologist:
Case type: Surgical Case

Entire report and diagnosis completed by:

Surgical Pathology Report		Page 2 of 2
File under: Pathology		

Source: NCI Genomic Data Commons file eeaaf6a4-63e4-43ee-90c5-995a6e178958 (TCGA-EL-A3ZT.F19BB96F-31BF-466F-B1FB-0CBB1EE89A88.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).